Somatic mutation profile of tumor specimen 0E0THJ from CCDI case PBCUMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0THJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a0f431-e754-4b06-a477-7add63f24ded.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0THM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1fdb23c-6c80-4c62-842b-37a27aa0540c

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEP1A | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 21/770 reads (3%) | called by muse, mutect2
- KRT27 | c.558C>T p.S186= | Silent (SNP) | VAF 65/1184 reads (5%) | catalogued as COSV56971364; called by muse, mutect2
- SCARF1 | c.1869G>A p.A623= | Silent (SNP) | VAF 44/1008 reads (4%) | catalogued as rs377102796, COSV53958832; called by muse, mutect2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 28/1116 reads (3%) | called by muse, mutect2
